Somatic mutation profile of tumor specimen C3L-06072-54 (aliquot CPT0369720002) from CPTAC case C3L-06072, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 37.6 years (13,741 days).
Specimen C3L-06072-54: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 30652eed-1bb7-470e-b17c-7db3106bd624.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06072-51 (Buccal Cell Normal), aliquot CPT0369690002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5d86ac8b-f941-4ba4-93a5-fd621b6d3f51

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 10, Silent 3, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLEC12A | c.104C>G p.P35R | Missense Mutation (SNP) | VAF 87/199 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV58561801; called by muse, mutect2, varscan2
- FLOT2 | c.469G>A p.V157M | Missense Mutation (SNP) | VAF 128/264 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs778214135; called by muse, mutect2, varscan2
- KMT2D | c.9391_9393del p.P3131del | In Frame Del (DEL) | VAF 157/363 reads (43%) | catalogued as rs748239185; called by mutect2, pindel, varscan2
- SLC6A7 | c.592G>A p.V198I | Missense Mutation (SNP) | VAF 66/144 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs770458246, COSV57937780; called by muse, mutect2, varscan2
- SLIT2 | c.2515G>A p.V839I | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs770411162; called by muse, mutect2, varscan2
- ZNF469 | c.3304C>G p.P1102A (on ENST00000437464; = p.P1130A on NM_001367624.2) | Missense Mutation (SNP) | VAF 14/235 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.557); catalogued as rs931187854; called by muse, mutect2
- ZNF598 | c.2554G>C p.A852P | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.118); catalogued as COSV50192197; called by mutect2, varscan2
- CAMK2D | c.437G>A p.S146N | Missense Mutation (SNP) | VAF 103/211 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- DIP2A | c.1960del p.Q654Sfs*5 | Frame Shift Del (DEL) | VAF 109/246 reads (44%) | called by mutect2, varscan2
- MYH11 | c.32A>T p.E11V | Missense Mutation (SNP) | VAF 154/327 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- OPRD1 | c.872G>A p.R291Q | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- TBX18 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 125/256 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIAA1586 | c.2227T>C p.L743= | Silent (SNP) | VAF 27/56 reads (48%) | called by muse, varscan2
- TAS2R1 | c.327C>T p.S109= | Silent (SNP) | VAF 11/125 reads (9%) | catalogued as rs369526627, COSV66779311; called by muse, mutect2
- TDRD9 | c.2776C>T p.L926= | Silent (SNP) | VAF 51/317 reads (16%) | called by muse, mutect2, varscan2
